Somatic mutation profile of tumor specimen TARGET-10-PAUBLL-09A (aliquot TARGET-10-PAUBLL-09A-01D) from TARGET case TARGET-10-PAUBLL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.2 years (2,617 days).
Specimen TARGET-10-PAUBLL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a52f54b-1d23-4443-9faf-ba8a0c838bd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAUBLL-10A (Blood Derived Normal), aliquot TARGET-10-PAUBLL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5406fd96-5317-493a-9ad5-25b5011deb42

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C17orf75 | c.509A>G p.D170G | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs374564813; called by muse, mutect2, varscan2
- ENTPD6 | c.1330G>A p.G444S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140620202, COSV100737206; called by muse, mutect2, varscan2
- FRMPD3 | c.2711G>A p.R904Q | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.006); catalogued as rs1265705792, COSV52188496; called by muse, mutect2
- GNB1 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66101788; called by muse, mutect2, varscan2
- GPRASP1 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs780293292, COSV64356343; called by muse, mutect2, varscan2
- KCNV2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs753070311, COSV66056636; called by muse, mutect2, varscan2
- NOTCH1 | c.5099C>A p.A1700D | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53072224, COSV53085928; called by muse, mutect2, varscan2
- PAXBP1 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs545150914, COSV51606860; called by muse, mutect2, varscan2
- RPL10 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV50009981, COSV50010241; called by muse, mutect2, varscan2
- SLC9A3 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as rs200473589, COSV53804656; called by muse, mutect2, varscan2
- TMEM89 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs551791003, COSV56574979; called by muse, mutect2, varscan2
- RPL3L | c.523C>A p.Q175K | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2
- MID1 | c.1371C>A p.T457= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV58194724; called by muse, mutect2
- RAB11B | c.351C>T p.I117= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs79270668, COSV60086241; called by muse, mutect2, varscan2
- TP53BP1 | c.4017G>C p.G1339= | Silent (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- ZBTB7B | c.285G>T p.G95= (on ENST00000292176; = p.G129= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- PENK | c.138+29C>G | Intron (SNP) | VAF 25/69 reads (36%) | called by muse, mutect2, varscan2
- TTN | c.10360+1398A>G | Intron (SNP) | VAF 4/59 reads (7%) | called by muse, mutect2
